Somatic mutation profile of tumor specimen 0DKZ8M from CCDI case PBBYTY, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Craniopharyngioma, adamantinomatous; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 11.6 years (4,242 days).
Specimen 0DKZ8M: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c360d9f5-5034-425b-94cf-e5cc1256831c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DKZ8G (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ca444b97-f7f1-41cc-aaf3-eb30094df215

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Missense Mutation 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 92/1091 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- ZBTB33 | c.1313G>T p.G438V | Missense Mutation (SNP) | VAF 46/1077 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); catalogued as rs782463731; called by muse, mutect2
- EWSR1 | c.869A>C p.E290A | Missense Mutation (SNP) | VAF 68/1077 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.677); called by muse, mutect2
- XDH | c.1733T>A p.L578Q | Missense Mutation (SNP) | VAF 49/741 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.534); called by muse, mutect2
